Somatic mutation profile of tumor specimen TCGA-RD-A8N1-01A (aliquot TCGA-RD-A8N1-01A-12D-A364-08) from TCGA case TCGA-RD-A8N1, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.5 years (25,737 days).
Specimen TCGA-RD-A8N1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d728b04-118c-43c6-9b35-e0409a30ecde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8N1-10A (Blood Derived Normal), aliquot TCGA-RD-A8N1-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a807e8db-8e35-4162-b0d7-77dc12fbd134

The open-access MAF lists 108 somatic variants for this specimen: 84 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 21, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 3, Intron 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519980, COSV52687391, COSV52701599, COSV52735850, COSV99377692; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.2645C>A p.P882H | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV101330089; called by muse, mutect2, varscan2
- AHNAK | c.1643T>C p.L548P | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV99947946; called by muse, mutect2, varscan2
- AKAP6 | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99801620; called by muse, mutect2, varscan2
- ALPL | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100876906; called by muse, mutect2, varscan2
- AMBN | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs867402927, COSV100534370, COSV100534409; called by muse, mutect2, varscan2
- AOX1 | c.3142G>A p.G1048R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99613657; called by muse, mutect2, varscan2
- APOB | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as rs767495928, COSV99266089; called by muse, mutect2, varscan2
- ARHGDIA | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.717); catalogued as COSV99482589; called by muse, mutect2
- BABAM2 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100142197; called by muse, mutect2, varscan2
- BCL11A | c.2159G>C p.C720S (on ENST00000335712 / NM_001365609.1; = p.C754S on NM_022893.4) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV100185823; called by muse, mutect2
- BPIFB4 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs763890373, COSV100971431, COSV100971552; called by muse, varscan2
- C1orf141 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100924351; called by muse, mutect2, varscan2
- CACNA1S | c.4453C>A p.Q1485K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1282907317, COSV100755095; called by muse, mutect2
- CATSPERB | c.833T>G p.F278C | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99831389; called by muse, mutect2, varscan2
- CCDC63 | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs766597229, COSV100370423; called by muse, mutect2, varscan2
- CD163 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100775898; called by muse, mutect2, varscan2
- CDH8 | c.2272T>C p.S758P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100182133; called by muse, mutect2, varscan2
- CEACAM7 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV50073972; called by muse, mutect2
- CFAP52 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100235302; called by muse, mutect2, varscan2
- CPXCR1 | c.348A>T p.K116N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99342241; called by muse, mutect2, varscan2
- CYP4F12 | c.505A>C p.K169Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV100215897; called by muse, mutect2, varscan2
- CYRIA | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100838208, COSV100838440; called by muse, mutect2
- DCLK2 | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56205169, COSV99652288; called by muse, mutect2, varscan2
- DIAPH2 | c.2546G>A p.R849K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV100233329; called by muse, mutect2, varscan2
- DMXL2 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs746881175, COSV51841117; called by muse, mutect2, varscan2
- DNAH10 | c.2879T>C p.I960T (on ENST00000409039; = p.I899T on NM_207437.3) | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV68989546; called by muse, mutect2, varscan2
- DNER | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100519279; called by muse, mutect2, varscan2
- DOCK10 | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as rs902053187, COSV99289944; called by muse, mutect2, varscan2
- FAM72A | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.346); catalogued as COSV100367267; called by muse, mutect2, varscan2
- GRK1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1382545439, COSV100175375; called by muse, mutect2
- H3C7 | c.68C>G p.T23S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99769136; called by muse, mutect2, varscan2
- IL27RA | c.1778C>G p.P593R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.231); catalogued as COSV99652216; called by muse, mutect2
- IL6R | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773270678, COSV100690863; called by muse, mutect2, varscan2
- JAG1 | c.1523G>A p.R508K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV54761587; called by muse, mutect2, varscan2
- KIF20A | c.2464G>T p.G822C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV101203122; called by muse, mutect2
- KRT84 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57772574, COSV99230914; called by muse, mutect2
- LRCH1 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV100243771; called by muse, mutect2
- MAGEL2 | c.2593A>C p.T865P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as COSV100045998; called by muse, mutect2, varscan2
- MAP2K7 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1383410204, COSV67608539; called by muse, mutect2, varscan2
- MDN1 | c.3175A>C p.T1059P | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101021464; called by muse, mutect2
- METTL17 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228255; called by muse, mutect2, varscan2
- MPV17L2 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs760946540, COSV99718017; called by muse, mutect2, varscan2
- MTF1 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.824); catalogued as COSV100886523; called by muse, mutect2, varscan2
- MTREX | c.2481+1G>C p.X827_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100044162; called by muse, mutect2
- NF1 | c.3651T>G p.D1217E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.571); catalogued as rs1135402846, COSV100647356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NME8 | c.1248-2A>G p.X416_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | catalogued as COSV52249112, COSV99553442; called by muse, mutect2, varscan2
- NSD3 | c.2886G>C p.Q962H | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100395371; called by muse, mutect2, varscan2
- OR14I1 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.145); catalogued as COSV100700491; called by muse, mutect2
- PCDH17 | c.3352C>G p.L1118V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.967); catalogued as COSV100931716; called by muse, mutect2, varscan2
- PCDHAC1 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99166820; called by muse, mutect2, varscan2
- PCDHB14 | c.2230A>T p.T744S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV99506014; called by muse, mutect2, varscan2
- PCDHGA11 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.005); catalogued as COSV99538741; called by muse, mutect2, varscan2
- PIN4 | c.39A>C p.Q13H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as COSV99512503; called by muse, mutect2, varscan2
- PLEKHA8 | c.1374G>T p.R458S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99321858; called by muse, mutect2, varscan2
- PREX1 | c.2864C>A p.A955D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs747769384, COSV100906462, COSV100906965; called by muse, mutect2, varscan2
- PRSS33 | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1345243063, COSV53451257; called by muse, mutect2, varscan2
- PTPRT | c.3628G>T p.D1210Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100628081, COSV61998148; called by muse, mutect2, varscan2
- RAB3GAP1 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99072065; called by muse, mutect2, varscan2
- RBM19 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55688482; called by muse, mutect2, varscan2
- REST | c.1128C>A p.F376L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as COSV58361623; called by muse, mutect2, varscan2
- SCAF1 | c.3343G>C p.E1115Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100862196; called by muse, mutect2, varscan2
- SGIP1 | c.1808C>G p.A603G | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs746198900, COSV52779742, COSV99391824; called by muse, mutect2, varscan2
- SHOC1 | c.3248C>G p.P1083R | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597724; called by muse, mutect2
- SLC1A7 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1390804069, COSV101019654; called by muse, mutect2
- SMC3 | c.2051A>C p.K684T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV100699937; called by muse, mutect2, varscan2
- SORCS2 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373666034, COSV61186863; called by muse, mutect2
- SOX7 | c.722del p.P241Rfs*30 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV100449166; called by mutect2, pindel, varscan2
- SPATA31D1 | c.170A>T p.N57I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV100782789, COSV100782827; called by muse, mutect2, varscan2
- TAF1L | c.3011A>G p.K1004R | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99644853; called by muse, mutect2, varscan2
- TLR4 | c.1157G>A p.S386N (on ENST00000355622 / NM_138554.5; = p.S346N on NM_003266.4) | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as COSV100842786; called by muse, mutect2
- TM9SF4 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs1178053193, COSV99454710; called by muse, mutect2
- TNFRSF8 | c.89A>T p.H30L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99821572; called by muse, mutect2, varscan2
- USP9X | c.2370A>G p.I790M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100199451; called by muse, mutect2, varscan2
- ZMIZ2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV99536959; called by muse, mutect2
- ZNF341 | c.2372A>G p.K791R (on ENST00000375200 / NM_001282935.1; = p.K784R on NM_032819.4) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV100677891; called by muse, mutect2, varscan2
- ZNF506 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101475616; called by muse, mutect2
- GORASP2 | c.694_699+38del p.X232_splice | Splice Site (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- OXCT1 | c.148del p.V50* | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- PTEN | c.67_77del p.D24Yfs*16 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- RIC1 | c.564_574del p.D189Ifs*2 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- TRGV5 | c.284G>C p.S95T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- USP25 | c.218_250del p.A73_V83del | In Frame Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- ZNF596 | c.110_123del p.L37Sfs*35 | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | called by mutect2, pindel
- ANKRD30A | c.4068T>C p.F1356= (on ENST00000611781; = p.F1300= on NM_052997.2) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100653705; called by muse, mutect2, varscan2
- CCPG1 | c.1413C>T p.G471= | Silent (SNP) | VAF 37/259 reads (14%) | catalogued as rs1175395979, COSV99380448; called by muse, mutect2, varscan2
- CHST2 | c.1053G>A p.E351= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100535992; called by muse, mutect2, varscan2
- CNGA2 | c.1278A>T p.R426= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100323763; called by muse, mutect2
- FCRL3 | c.522T>C p.I174= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100943324; called by muse, mutect2
- IRF4 | c.978G>A p.A326= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs766676957, COSV101110789; called by muse, mutect2, varscan2
- KIF13A | c.72C>A p.T24= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52455573, COSV99436370; called by muse, mutect2, varscan2
- KIF22 | c.303G>A p.Q101= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99361236; called by muse, mutect2
- LRRC7 | c.4398A>T p.G1466= (on ENST00000651989 / NM_001370785.2; = p.G1386= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99227620; called by muse, mutect2, varscan2
- MFHAS1 | c.1116C>T p.I372= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV52280038; called by muse, mutect2, varscan2
- NCDN | c.1266C>T p.V422= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100622049; called by muse, mutect2
- NFASC | c.2445C>T p.S815= (on ENST00000339876 / NM_001378329.1; = p.S811= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs761408551, COSV58366033; called by muse, mutect2
- OR5K1 | c.153A>C p.T51= | Silent (SNP) | VAF 27/297 reads (9%) | catalogued as COSV100220980; called by muse, mutect2
- PDE6C | c.1554G>A p.E518= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV101008778; called by muse, mutect2
- PLCB2 | c.357G>A p.K119= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99542201; called by muse, varscan2
- PTCD2 | c.294A>G p.L98= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV100348976; called by muse, mutect2
- RCN1 | c.363C>T p.A121= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99277298; called by muse, mutect2
- SLC30A7 | c.897C>G p.P299= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs1164672989, COSV100725542; called by muse, mutect2, varscan2
- SLC39A10 | c.2058C>T p.L686= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs759918052, COSV100660637; called by muse, mutect2
- SRGAP1 | c.147G>C p.L49= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV100754806; called by muse, mutect2, varscan2
- ZNF479 | c.801A>G p.K267= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100482801; called by muse, mutect2, varscan2
- GLOD4 | chr17:782559 G>A | 5'Flank (SNP) | VAF 5/21 reads (24%) | catalogued as rs1177047458, COSV100022633; called by muse, mutect2, varscan2
- GSPT1 | c.-63+172G>A | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101341738; called by muse, mutect2
- NACA | c.71-2170C>G | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100771393; called by muse, mutect2
